Somatic mutation profile of tumor specimen TCGA-B6-A409-01A (aliquot TCGA-B6-A409-01A-11D-A243-09) from TCGA case TCGA-B6-A409, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 44.3 years (16,178 days).
Specimen TCGA-B6-A409-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 579c098b-473c-4f94-a005-4e7b8dc6a4d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A409-10A (Blood Derived Normal), aliquot TCGA-B6-A409-10A-01D-A243-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/baa67390-15b8-409a-8c64-cef7a1d355eb

The open-access MAF lists 40 somatic variants for this specimen: 24 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 14, Frame Shift Del 3, Intron 2, Nonsense Mutation 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF9 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99492369; called by muse, mutect2, varscan2
- BCOR | c.8C>G p.S3* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV60704890, COSV60705153; called by muse, mutect2, varscan2
- CKS1B | c.110T>G p.L37R | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100460524; called by muse, mutect2, varscan2
- COL12A1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.041); catalogued as rs1430510419, COSV59408066; called by muse, mutect2
- EOLA2 | c.265A>T p.I89F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV100778122; called by muse, mutect2, varscan2
- FGD6 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs757525900, COSV100676801; called by muse, mutect2, varscan2
- GABRG1 | c.593A>G p.D198G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99778717; called by muse, mutect2, varscan2
- HRH2 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.49); catalogued as COSV51573872; called by muse, mutect2, varscan2
- IGSF1 | c.3070C>A p.P1024T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.305); catalogued as COSV100812302; called by muse, mutect2, varscan2
- MDN1 | c.12377C>A p.A4126D | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101021813; called by muse, mutect2, varscan2
- MYLK4 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99193892; called by muse, mutect2, varscan2
- NMT1 | c.90C>A p.C30* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99364985; called by muse, mutect2, varscan2
- OR10G2 | c.83G>C p.R28T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.653); catalogued as COSV101606971, COSV73390400; called by muse, mutect2, varscan2
- PSG11 | c.954C>G p.I318M | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV60453688; called by muse, mutect2
- PTBP2 | c.618C>A p.H206Q (on ENST00000426398 / NM_001300986.2; = p.H198Q on NM_021190.4) | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100930271; called by muse, mutect2
- RIPK4 | c.2381G>A p.R794Q (on ENST00000352483; = p.R746Q on NM_020639.3) | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.14); catalogued as rs144880660; called by muse, mutect2, varscan2
- SLC9A8 | c.1641C>T p.D547= | Splice Region (SNP) | VAF 9/81 reads (11%) | catalogued as COSV100846314; called by muse, mutect2
- TP53 | c.755dup p.T253Hfs*11 | Frame Shift Ins (INS) | VAF 15/45 reads (33%) | catalogued as COSV53278781, COSV53837621; called by mutect2, pindel, varscan2
- VPS51 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as rs375386887; called by mutect2, varscan2
- ZSWIM3 | c.986G>A p.R329K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV99666947; called by muse, mutect2, varscan2
- IFNAR1 | c.1523_1524del p.I508Kfs*10 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by pindel, varscan2
- MLLT6 | c.609_619del p.S204Rfs*42 | Frame Shift Del (DEL) | VAF 3/23 reads (13%) | called by mutect2, pindel
- NOMO1 | c.1750G>C p.E584Q | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.322); called by muse, mutect2
- VGLL4 | c.522_559del p.N174Kfs*20 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, varscan2
- CDH6 | c.2029C>T p.L677= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV99420761; called by muse, mutect2
- COG3 | c.975A>G p.Q325= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs1350303754, COSV100596734; called by muse, mutect2, varscan2
- CUBN | c.6978A>G p.G2326= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs200190000, COSV100913492; called by muse, mutect2, varscan2
- F13A1 | c.1386G>T p.G462= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV53559228; called by muse, mutect2, varscan2
- FLNC | c.7248C>T p.L2416= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100368704; called by muse, mutect2
- INTS1 | c.2235C>T p.A745= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs368809979; called by muse, mutect2, varscan2
- NKX2-2 | c.414G>A p.A138= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV101010472, COSV65819997; called by muse, mutect2, varscan2
- ORC5 | c.1125T>C p.A375= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs760013812, COSV99857379; called by muse, mutect2, varscan2
- OTX2 | c.177G>A p.K59= (on ENST00000408990 / NM_172337.3; = p.K67= on NM_021728.4) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV59766748; called by muse, mutect2, varscan2
- RYR1 | c.2655C>T p.R885= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100616931; called by muse, mutect2, varscan2
- SEPTIN5 | c.600G>A p.R200= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV100820464; called by muse, mutect2, varscan2
- SLC6A8 | c.1386G>A p.V462= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV99466271; called by muse, mutect2
- SOX4 | c.171G>T p.G57= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99782173; called by muse, mutect2
- ZBTB21 | c.447C>T p.V149= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs987984427, COSV100177356; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7270G>A | Intron (SNP) | VAF 61/118 reads (52%) | catalogued as rs760332508, COSV63389546; called by muse, mutect2, varscan2
- KITLG | c.130-2206G>A | Intron (SNP) | VAF 25/60 reads (42%) | catalogued as rs534880565, COSV99933551; called by muse, mutect2, varscan2
